Gene-level copy-number profile of tumor specimen TCGA-HB-A43Z-01A from TCGA case TCGA-HB-A43Z, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 58.1 years (21,233 days).
Specimen TCGA-HB-A43Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.0481cd5d-3183-4ef5-8849-7305ec2eb9a2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HB-A43Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9fc248ff-e11d-479b-b629-cb88973e8743

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 4,241; copy number 2: 19,765; copy number 3: 16,574; copy number 4: 12,334; copy number 5: 3,918; copy number 6: 2,532; copy number 7: 263; copy number 8: 108; copy number 9: 12; copy number 10: 13; copy number 11: 6; copy number 12: 1; copy number 13: 1; copy number 14: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HB-A43Z-01A-11D-A24M-01): tumor purity 0.92, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:75,210,154–75,431,588, 13 genes: VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,743,755, 5 genes: AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr10:76,835,377–77,638,369, 6 genes (within-gene range 0–1): AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1.
- chr10:87,863,625–88,259,372, 6 genes (within-gene range 0–1): PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr13:36,168,217–36,490,441, 8 genes: SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1, H2ACP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,850 genes in 94 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:49,025,595–104,226,678, 903 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:106,544,342–121,580,524, 378 genes, copy number 5–13 (broad region; genes not listed).
- chr1:168,540,768–173,207,331, 103 genes, copy number 5 (broad region; genes not listed).
- chr1:189,868,001–192,957,713, 24 genes, copy number 5–6 (within-gene range 4–6): AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1.
- chr1:195,747,024–199,393,307, 47 genes, copy number 5–6: AL353709.1, LINC01724, KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9, NEK7, PRR13P1, AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1.
- chr1:212,916,787–216,423,448, 34 genes, copy number 5 (within-gene range 4–5): AC104333.4, VASH2, ANGEL2, RPS6KC1, RPL31P13, AL592402.1, AC096639.1, PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1, LINC02775, SMYD2, AL929236.1, PTPN14, AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13, GAPDHP24, AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1.
- chr1:218,881,600–225,399,292, 122 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:47,335,315–91,767,701, 836 genes, copy number 6–10 (within-gene range 6–15) (broad region; genes not listed).
- chr3:107,220,744–115,721,490, 144 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr5:44,495,099–52,282,859, 39 genes, copy number 5: LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11.
- chr5:91,843,687–94,739,436, 32 genes, copy number 6: PCBP2P3, AC093298.1, AC114316.1, AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1, AC026408.1, POLD2P1, NR2F1-AS1, NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1, AC117528.1, KIAA0825, MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1.
- chr6:148,567,378–149,492,289, 15 genes, copy number 5: SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1, TAB2, TAB2-AS1, AL031056.2, RN7SL234P, FABP12P1, SUMO4, ZC3H12D, AL031133.1.
- chr6:149,594,873–154,510,685, 99 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr7:57,209,865–63,011,569, 35 genes, copy number 5 (within-gene range 3–5): AC099654.1, RNU7-157P, AC099654.12, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1, RNU6-417P.
- chr7:97,928,082–98,310,441, 14 genes, copy number 6: AC079781.4, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1, BRI3.
- chr7:99,876,958–100,428,992, 44 genes, copy number 5 (within-gene range 2–5): TRIM4, GJC3, AC004522.3, Y_RNA, AC004522.1, AZGP1, AC004522.4, AZGP1P1, AC004522.2, AC004522.5, ZKSCAN1, ZSCAN21, ZNF3, COPS6, MCM7, MIR25, MIR93, MIR106B, AP4M1, TAF6, AC073842.2, CNPY4, MBLAC1, AC073842.1, RPL7P60, LAMTOR4, MAP11, MIR4658, GAL3ST4, GPC2, STAG3, CASTOR3, PVRIG, SPDYE3, PMS2P1, Y_RNA, STAG3L5P, STAG3L5P-PVRIG2P-PILRB, PILRB, PVRIG2P, MIR6840, PILRA, AC005071.1, ZCWPW1.
- chr8:76,162,119–79,666,158, 31 genes, copy number 5: AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1, AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2.
- chr8:87,540,835–90,095,475, 24 genes, copy number 5: AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1.
- chr9:101,398,873–102,256,710, 12 genes, copy number 5 (within-gene range 4–5): ZNF189, ALDOB, AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20, GRIN3A, PPP3R2, MTND3P4, ARL2BPP7, RNU6-329P.
- chr11:70,324,871–89,704,658, 431 genes, copy number 5–9 (within-gene range 2–11) (broad region; genes not listed).
- chr11:90,555,774–97,259,987, 126 genes, copy number 5–7 (broad region; genes not listed).
- chr11:100,336,856–124,030,634, 524 genes, copy number 5–14 (broad region; genes not listed).
- chr11:124,093,592–124,399,024, 21 genes, copy number 5: OR10D4P, OR10N1P, VWA5A, OR10D1P, OR10D3, OR8F1P, OR8G3P, OR8G2P, OR8G7P, OR8G1, OR8G5, SLC5A4P1, OR8D1, OR8D2, OR8B7P, OR8B6P, OR8B5P, OR8B1P, OR8C1P, OR8B2, OR8B3.
- chr12:1,380,060–3,371,346, 59 genes, copy number 6: AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827, LINC02417.
- chr12:18,424,663–20,370,262, 26 genes, copy number 5: AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1.
- chr13:37,481,467–41,470,871, 68 genes, copy number 5 (broad region; genes not listed).
- chr13:64,958,097–77,975,529, 129 genes, copy number 5–8 (broad region; genes not listed).
- chr13:79,311,824–83,907,781, 33 genes, copy number 6: RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5, AL445255.1, GYG1P2, AL512782.1, RNU6-67P, AL353688.1, SLITRK1, AL355481.1, VENTXP2.
- chr13:84,867,514–99,590,508, 179 genes, copy number 5–9 (broad region; genes not listed).
- chr14:18,333,726–22,190,713, 250 genes, copy number 6 (broad region; genes not listed).
- chr14:104,474,678–106,875,071, 248 genes, copy number 6 (broad region; genes not listed).
- chr15:19,878,555–24,090,821, 177 genes, copy number 6 (broad region; genes not listed).
- chr15:35,081,144–44,663,678, 265 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr15:52,885,595–58,497,866, 84 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:68,867,289–79,516,148, 305 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr18:7,566,782–15,330,282, 226 genes, copy number 6 (broad region; genes not listed).
- chr18:27,225,742–44,579,953, 180 genes, copy number 6–14 (within-gene range 4–14) (broad region; genes not listed).
- chr18:51,845,007–60,902,726, 141 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr18:73,711,329–80,247,514, 134 genes, copy number 5–8 (broad region; genes not listed).
- chr19:34,172,504–36,105,108, 130 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
